Gene-level copy-number profile of tumor specimen TCGA-DX-A6YX-01A from TCGA case TCGA-DX-A6YX, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 68.1 years (24,871 days).
Specimen TCGA-DX-A6YX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.6d9b69bf-e5fc-4383-a63f-5d193a02d694.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A6YX-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8ad9b8c0-b7f6-4cdf-a626-cf3032d6b2a9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 56; copy number 1: 1,167; copy number 2: 22,223; copy number 3: 12,646; copy number 4: 20,965; copy number 5: 1,744; copy number 6: 493; copy number 7: 344; copy number 8: 10; copy number 9: 38; copy number 10: 115; copy number 12: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A6YX-01A-11D-A416-01): tumor purity 0.83, ploidy 2.94, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–2): MTAP, AL359922.1.
- chr9:21,892,188–21,995,301, 4 genes: AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.
- chr12:38,078,529–40,570,832, 36 genes (within-gene range 0–2): AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B, AC087897.1, AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.4, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1, RPL30P13, LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1, MUC19, AC107023.1.
- chr12:66,950,754–67,096,410, 1 gene (within-gene range 0–1): AC073530.1.
- chr12:67,131,567–67,352,039, 5 genes: RAB11AP2, GGTA2P, CAND1, AC078983.1, MRPL40P1.
- chr17:31,272,013–31,346,190, 5 genes: OMG, EVI2B, AC134669.1, EVI2A, AK4P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,958 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–152,676,574, 378 genes, copy number 6 (broad region; genes not listed).
- chr1:184,690,237–186,988,981, 43 genes, copy number 7: EDEM3, NIBAN1, RNU7-13P, LINC01633, RNA5SP72, RNF2, FTH1P25, TRMT1L, SWT1, RPL22P24, RPL5P5, Y_RNA, Y_RNA, AL356273.1, Y_RNA, AL356273.2, AL356273.3, IVNS1ABP, AL078644.1, GS1-279B7.1, RNU7-183P, MCRIP2P2, AL133383.2, LINC01350, Y_RNA, Y_RNA, AL133383.1, HMCN1, AL133553.1, AL133553.2, PRG4, TPR, RNU6-1240P, ODR4, PDC-AS1, PDC, AL096803.3, AL096803.1, AL096803.2, AL049198.1, PTGS2, PACERR, PLA2G4A.
- chr3:11,745–22,670,711, 317 genes, copy number 5 (broad region; genes not listed).
- chr3:87,742,543–90,261,708, 22 genes, copy number 7: RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr4:189,764,391–190,092,279, 23 genes, copy number 6 (within-gene range 2–6): FRG1-DT, LINC01596, FRG1, MLLT10P2, AF146191.2, TUBB7P, RNA5SP174, RNA5SP175, DUX4L9, FRG2, RARRES2P4, AGGF1P1, CLUHP4, DBET, U85056.1, DUX4L8, DUX4L7, DUX4L6, DUX4L5, DUX4L4, DUX4L1, DUX4L3, DUX4L2.
- chr8:11,247,626–12,388,296, 61 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr8:27,171,914–28,191,156, 29 genes, copy number 5–9: AC090150.1, STMN4, TRIM35, PTK2B, MIR6842, CHRNA2, EPHX2, GULOP, CLU, MIR6843, SCARA3, RNU6-1086P, AC013643.1, AC013643.3, MIR3622B, MIR3622A, AC013643.2, CCDC25, ESCO2, RNU6-1276P, PBK, AC104997.1, SCARA5, MIR4287, AC069113.1, AC069113.3, AC069113.2, NUGGC, ELP3.
- chr8:35,235,475–35,796,550, 1 gene, copy number 5 (within-gene range 1–5): UNC5D.
- chr8:35,525,176–46,028,892, 191 genes, copy number 5 (broad region; genes not listed).
- chr8:56,373,064–73,370,601, 252 genes, copy number 5–12 (within-gene range 3–12) (broad region; genes not listed).
- chr8:76,162,119–76,867,281, 10 genes, copy number 8 (within-gene range 3–8): AC011029.1, RNU2-54P, AC067773.1, LINC01109, LINC01111, ZFHX4-AS1, AC013509.1, MRPL9P1, ZFHX4, AC011716.1.
- chr8:81,244,156–91,219,236, 138 genes, copy number 5–10 (within-gene range 1–10) (broad region; genes not listed).
- chr8:102,451,763–104,467,055, 46 genes, copy number 5: HSPE1P14, RPS12P15, AP002852.1, RNU6-1224P, ODF1, POU5F1P2, KLF10, AP002851.1, ADI1P2, GASAL1, AZIN1, AP003696.1, MAILR, AP003354.1, RPL5P24, Y_RNA, NPM1P52, AP003550.1, ATP6V1C1, MTND1P5, MTCO1P4, MTCO2P4, LINC01181, BAALC-AS2, BAALC, BAALC-AS1, MIR3151, AC025370.1, FZD6, AC025370.2, CTHRC1, AC012213.3, RNU6-1011P, SLC25A32, AC012213.5, DCAF13, AC012213.2, AC012213.4, AC012213.1, RIMS2, PTMAP15, AC007751.1, AC090686.1, DPYS, DCSTAMP, AP003471.1.
- chr8:105,929,126–105,929,238, 1 gene, copy number 5: Y_RNA.
- chr8:115,408,496–116,403,757, 6 genes, copy number 5 (within-gene range 1–5): TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1.
- chr8:121,612,116–122,127,184, 5 genes, copy number 5: HAS2, HAS2-AS1, LINC02855, AC037486.1, MRPS36P3.
- chr8:122,485,194–122,733,804, 1 gene, copy number 5 (within-gene range 1–5): LINC01151.
- chr8:122,671,291–123,042,302, 10 genes, copy number 5: AC100872.1, AC100872.2, CDK5P1, AC016405.3, AC016405.2, ZHX2, AC016405.1, AC104316.2, AC104316.1, DERL1.
- chr8:125,466,939–128,564,679, 46 genes, copy number 5–9 (within-gene range 1–9): AC091114.1, AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824.
- chr8:130,052,104–130,443,674, 1 gene, copy number 6 (within-gene range 1–6): ASAP1.
- chr8:130,248,287–130,655,712, 3 genes, copy number 6: AC009682.1, AC139019.1, AC090987.1.
- chr8:132,507,962–133,902,407, 29 genes, copy number 5–7 (within-gene range 1–7): HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1.
- chr8:134,477,788–139,704,109, 39 genes, copy number 7: ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56, LINC01591, AC040914.1, KHDRBS3, MAPRE1P1, RNU1-35P, LINC02055, AC103955.1, AC023781.1, RNU6-144P, ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B, COL22A1, AC027541.1, AC100807.1, AC100807.2, AC087354.1, AC090093.1, KCNK9.
- chr8:140,505,813–143,541,447, 87 genes, copy number 6–10 (within-gene range 3–10) (broad region; genes not listed).
- chr8:144,262,045–145,066,685, 58 genes, copy number 7: BOP1, HSF1, DGAT1, AC233992.1, MIR6848, SCRT1, SLC52A2, TMEM249, AC233992.2, FBXL6, ADCK5, CPSF1, MIR939, MIR1234, MIR6849, AC233992.3, SLC39A4, VPS28, TONSL, MIR6893, TONSL-AS1, CYHR1, AC084125.1, KIFC2, FOXH1, PPP1R16A, AC084125.2, GPT, MFSD3, RECQL4, AC084125.4, LRRC14, LRRC24, C8orf82, ARHGAP39, AC084125.3, Metazoa_SRP, AF186192.1, AF186192.2, AF186192.3, ZNF251, ZNF34, RN7SL395P, RPL8, MIR6850, ZNF517, ZNF7, COMMD5, AF235103.3, ZNF250, ZNF16, ZNF252P, AF235103.1, TMED10P1, ZNF252P-AS1, AF235103.2, AC139103.1, C8orf33.
- chr11:21,260,061–21,383,909, 3 genes, copy number 7: AC090857.2, AC099730.1, RNA5SP337.
- chr12:125,858,132–128,244,573, 62 genes, copy number 5 (broad region; genes not listed).
- chr14:21,950,406–22,530,378, 96 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,167. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
